Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A184, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A184-06A (Metastatic).

DOB/Age/Sex: - - - - -
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

ICB-0-3 8720/3
Melanoma NOS 8720/3
Site Code: Wrist, skin C44.6
years Male 12/19/10
w

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Metastatic melanoma right wrist. Wide local excision melanoma right wrist-> histo.

MACROSCOPIC DESCRIPTION

"METASTATIC MELANOMA RIGHT WRIST SUTURE PROXIMAL". An oriented oval shaped piece of skin 65 x 60 x 26mm, orientated with a suture half along a long edge margin indicating proximal; it is arbitrarily designated as 12 o'clock. The 12 o'clock margin inked blue and the 6 o'clock margin inked black. The cut surface shows an ill defined subcutaneous nodular mass 35 x 30 x 20mm with solid variably pigmented cut surface. Two representative slices from the centre of the mass embedded in blocks A - D. Each slice in two blocks respectively.

MICROSCOPIC REPORT

"METASTATIC MELANOMA RIGHT WRIST SUTURE PROXIMAL": The sections show nodular subcutaneous tumour composed of pleomorphic epithelioid and spindle cells associated with pigment, consistent with melanoma. There is adjacent haemorrhage and granulation tissue in the overlying dermis. A definite junctional component is not seen. No residual lymph node is identified. Where the deep tissues are intact the tumour appears to be 0.5mm from the inked deep/12 o'clock margin. In some sections the tumour appears to abut the deep aspect of the section, however no ink is seen and the true margin tissue may have retracted.

SPECIAL INVESTIGATIONS

The tumour cells show patchy positive staining with S-100, HMB-45 and Melan A.

COMMENT

Clinical and operative correlation is required.

SUMMARY

Skin and subcutis of right wrist - Melanoma.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file 3bd42e24-75f5-405b-a8d7-6150f9902495 (TCGA-EE-A184.00238EE4-0014-4CB6-9E79-C93B8EF7BD04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).